Gene-level copy-number profile of tumor specimen TARGET-10-PATZSL-09A from TARGET case TARGET-10-PATZSL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,663 days).
Specimen TARGET-10-PATZSL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.d1790922-9417-574c-83ee-7d45c6553637.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATZSL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 398 have no estimate.
https://portal.gdc.cancer.gov/files/2ec803d6-a1e1-40f9-aaa6-123714aebdfb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 548; copy number 1: 1,434; copy number 2: 57,399; copy number 3: 812; copy number 4: 12; copy number 5: 20.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,322,730, 11 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr13:31,960,325–31,961,946, 1 gene: AC002525.1.
- chr14:22,449,113–22,469,698, 7 genes: TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3.
- chr19:51,639,478–51,646,801, 2 genes: AC018755.4, SIGLEC14.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:49,496,763–49,554,414, 2 genes, copy number 5 (within-gene range 2–5): AC090155.2, AC090155.1.
- chr17:36,110,150–36,457,535, 18 genes, copy number 5: RN7SL301P, AC243829.2, AC243829.7, TBC1D3B, AC243829.1, CCL3L3, CCL4L2, AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, RNU6-1192P, TBC1D3F, TBC1D3J.

Autosomal genes at a single copy (total copy number 1): 1,405. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
